Gene-level copy-number profile of tumor specimen ALCH-AE0Y-TTP1-A from ALCHEMIST case ALCH-AE0Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 52.5 years (19,187 days).
Specimen ALCH-AE0Y-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 54ec3fb7-ead9-4bc0-97cd-7b2d649dd946.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE0Y-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/55b3de29-c30f-4c61-8000-8c3b7a3e28c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1,973; copy number 2: 20,459; copy number 3: 17,710; copy number 4: 13,450; copy number 5: 2,340; copy number 6: 1,771; copy number 7: 1,011; copy number 8: 174; copy number 9: 4.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:121,593,379–121,630,295, 1 gene: FBXO40.
- chr8:69,987,415–69,987,697, 1 gene: SUMO2P20.
- chr8:144,049,079–144,063,965, 3 genes: SMPD5, OPLAH, MIR6846.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,297 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–2,633,016, 171 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:3,812,086–10,630,758, 148 genes, copy number 5–8 (broad region; genes not listed).
- chr1:11,066,618–11,099,869, 1 gene, copy number 7 (within-gene range 4–7): EXOSC10.
- chr1:11,099,675–12,693,020, 58 genes, copy number 7: EXOSC10-AS1, MTOR, MTOR-AS1, RNU6-537P, ANGPTL7, RNU6-291P, RPL39P6, UBIAD1, UBE2V2P3, MTCYBP45, DISP3, AL590989.1, LINC01647, FBXO2, FBXO44, FBXO6, MAD2L2, DRAXIN, AGTRAP, C1orf167, C1orf167-AS1, MTHFR, CLCN6, AL021155.2, AL021155.3, NPPA, AL021155.1, NPPB, SBF1P2, AL021155.4, RNU5E-1, RNU5E-4P, KIAA2013, PLOD1, MFN2, AL096840.1, MIIP, Y_RNA, MIR6729, RN7SL649P, TNFRSF8, RNU6-777P, RPL23AP89, AL357835.1, MIR7846, TNFRSF1B, MIR4632, RPL10P17, SNORA70, VPS13D, SNORA59A, LINC02766, DHRS3, RNU6ATAC18P, MIR6730, AC254633.1, AADACL4, AC244670.1.
- chr1:13,474,973–22,921,500, 249 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:23,706,901–25,590,356, 56 genes, copy number 5: ELOA-AS1, ELOA, PITHD1, LYPLA2, GALE, HMGCL, FUCA1, CNR2, BTBD6P1, AL590609.2, MIR378F, H3P1, PNRC2, SRSF10, AL590609.1, AL591178.1, MYOM3, MYOM3-AS1, IL22RA1, IFNLR1, LINC02800, GRHL3-AS1, GRHL3, STPG1, NIPAL3, RCAN3AS, RCAN3, NCMAP-DT, NCMAP, AL445686.1, Y_RNA, SRRM1, CLIC4, RNU6-1208P, RUNX3, MIR6731, RUNX3-AS1, AL445471.1, MIR4425, LINC02793, AL050344.1, IFITM3P7, AL031432.1, SYF2, RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1, TMEM50A, RHCE, AL031284.1, MACO1, LDLRAP1, AL606491.1.
- chr1:37,154,761–43,991,170, 222 genes, copy number 6 (broad region; genes not listed).
- chr2:74,186,172–74,217,565, 1 gene, copy number 5 (within-gene range 3–5): MTHFD2.
- chr2:74,211,604–88,016,547, 239 genes, copy number 5 (broad region; genes not listed).
- chr2:147,810,346–151,828,492, 50 genes, copy number 5: AC009480.2, ACVR2A, RNU6-1275P, AC009480.1, ORC4, MBD5, AC019226.1, AC019226.2, AC019070.1, USP12P2, RPS29P8, EPC2, RNU2-9P, UBBP3, KIF5C-AS1, RPS20P13, USP8P2, KIF5C, AC105402.1, LYPD6B, TXNP5, AC009230.1, FAM8A3P, LYPD6, RPL17P13, MMADHC, MMADHC-DT, RNU6-601P, LINC01931, LINC01818, LINC01817, RND3, LINC01920, AC104777.2, AC104777.1, LINC02612, AC023469.2, AC023469.1, AC018731.1, FABP5P10, RBM43, NMI, TNFAIP6, MIR4773-1, MIR4773-2, RN7SL124P, RIF1, NEB, ARL5A, AC097448.1.
- chr2:156,011,530–156,342,348, 3 genes, copy number 6: LINC01876, HEBP2P1, NR4A2.
- chr2:157,318,631–174,043,880, 227 genes, copy number 5–9 (broad region; genes not listed).
- chr2:239,048,168–242,175,634, 91 genes, copy number 5 (broad region; genes not listed).
- chr3:104,502,700–105,869,552, 3 genes, copy number 6: AC091804.1, ALCAM, CBLB.
- chr5:58,198–22,853,344, 364 genes, copy number 6 (broad region; genes not listed).
- chr7:37,032–68,724,048, 1,237 genes, copy number 5–7 (broad region; genes not listed).
- chr7:89,754,620–93,361,123, 57 genes, copy number 6: RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50.
- chr8:99,013,266–99,877,580, 1 gene, copy number 8 (within-gene range 2–8): VPS13B.
- chr8:99,527,826–104,589,024, 125 genes, copy number 5–8 (broad region; genes not listed).
- chr11:43,827,517–43,880,726, 1 gene, copy number 5 (within-gene range 2–5): AC087521.2.
- chr11:43,880,811–43,920,944, 3 genes, copy number 5: ALKBH3, SEC14L1P1, ALKBH3-AS1.
- chr12:12,310–27,972,733, 708 genes, copy number 5 (broad region; genes not listed).
- chr14:49,768,130–69,531,551, 415 genes, copy number 6 (broad region; genes not listed).
- chr14:95,620,914–96,489,427, 26 genes, copy number 6 (within-gene range 4–6): AL133467.2, AL133467.4, TCL6, AL133467.5, AL133467.3, AL133467.6, TCL1B, TCL1A, AL139020.1, AL133167.1, TUNAR, AL137190.1, C14orf132, BDKRB2, AL355102.2, AL355102.1, CKS1BP1, AL355102.5, BDKRB1, AL355102.4, AL355102.3, ATG2B, GSKIP, RNU2-33P, AK7, PEBP1P1.
- chr14:99,397,748–99,535,044, 3 genes, copy number 7 (within-gene range 4–7): SETD3, RNU6-91P, CCNK.
- chr14:99,512,501–99,513,576, 1 gene, copy number 7 (within-gene range 4–7): AL110504.1.
- chr14:101,964,573–102,056,443, 1 gene, copy number 6 (within-gene range 4–6): DYNC1H1.
- chr14:102,036,315–105,450,106, 121 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr14:105,583,731–106,879,812, 194 genes, copy number 6 (broad region; genes not listed).
- chr16:1,510,427–1,612,072, 1 gene, copy number 6 (within-gene range 3–6): IFT140.
- chr16:1,528,688–1,702,280, 11 genes, copy number 6 (within-gene range 3–6): TMEM204, AL031719.1, AL031719.2, Z97633.1, AL133297.1, AL133297.2, CRAMP1, Z97652.1, AL031708.1, JPT2, AL031009.1.
- chr16:28,097,976–28,211,965, 4 genes, copy number 6: XPO6, TPRKBP2, AC136611.1, RNY1P10.
- chr18:39,841,174–40,144,504, 5 genes, copy number 5: LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45.
- chr22:20,707,691–24,178,628, 272 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr22:26,858,634–29,698,598, 74 genes, copy number 5 (broad region; genes not listed).
- chr22:30,262,829–30,674,134, 30 genes, copy number 7: OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157, RNF215, SEC14L2, AC004832.3, AC004832.5, RNU6-564P, AC004832.4, MTFP1, AC004832.6, AC004832.2, SEC14L3, AC004832.1, SDC4P, SEC14L4, SEC14L6, SIRPAP1, GAL3ST1, PES1, AC005006.1, TCN2, SLC35E4, DUSP18, AC003072.1, AC003072.2.
- chr22:38,111,495–41,529,273, 124 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,454. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
